Somatic mutation profile of tumor specimen ALCH-B005-TTP1-A (aliquot ALCH-B005-TTP1-A-1-0-D-A667-36) from ALCHEMIST case ALCH-B005, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.5 years (25,751 days).
Specimen ALCH-B005-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b460b78-6629-4e9b-bd06-4a930f21a9fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B005-NB1-A (Blood Derived Normal), aliquot ALCH-B005-NB1-A-1-0-D-A667-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fdc4ece1-6c71-40a7-8b62-9daa0a1e3a99

The open-access MAF lists 372 somatic variants for this specimen: 254 protein-altering or splice-affecting, 72 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 218, Silent 72, Intron 18, Nonsense Mutation 14, 5'UTR 9, Frame Shift Del 8, 3'UTR 7, Splice Region 6, Splice Site 6, RNA 5, 3'Flank 4, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 286/539 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AFF3 | c.2855C>T p.P952L | Missense Mutation (SNP) | VAF 26/410 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs1450870964; called by muse, mutect2
- ANKRD26 | c.2527G>T p.E843* | Nonsense Mutation (SNP) | VAF 145/369 reads (39%) | catalogued as COSV65775975; called by muse, mutect2, varscan2
- ANKRD26 | c.2526G>C p.M842I | Missense Mutation (SNP) | VAF 142/366 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV101063012; called by muse, mutect2, varscan2
- ARHGAP17 | c.187del p.E63Rfs*9 | Frame Shift Del (DEL) | VAF 24/96 reads (25%) | catalogued as COSV51508273; called by mutect2, pindel, varscan2
- ARMC2 | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 52/368 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); catalogued as rs1314922232; called by muse, mutect2, varscan2
- ATP10A | c.2093C>A p.P698Q | Missense Mutation (SNP) | VAF 101/350 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100791636; called by muse, mutect2, varscan2
- ATP8A1 | c.1895C>T p.S632F | Missense Mutation (SNP) | VAF 43/258 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); catalogued as COSV104389585; called by muse, mutect2, varscan2
- BAZ1B | c.4375G>A p.D1459N | Missense Mutation (SNP) | VAF 95/307 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.023); catalogued as COSV59991641, COSV59993084; called by muse, mutect2, varscan2
- BCDIN3D | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as rs1000339377; called by muse, mutect2
- CASP7 | c.553-1G>A p.X185_splice | Splice Site (SNP) | VAF 19/265 reads (7%) | catalogued as rs780894394; called by muse, mutect2
- CD177 | c.1137C>A p.F379L | Missense Mutation (SNP) | VAF 119/257 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV100946061; called by muse, mutect2, varscan2
- CDH12 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99063499; called by muse, mutect2, varscan2
- CGNL1 | c.871G>C p.A291P | Missense Mutation (SNP) | VAF 125/494 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs749980112; called by muse, mutect2, varscan2
- CNTNAP3 | c.3082G>A p.V1028I | Missense Mutation (SNP) | VAF 381/1346 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1368677445; called by muse, mutect2, varscan2
- COL6A6 | c.2845G>A p.D949N | Missense Mutation (SNP) | VAF 183/469 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs745698681, COSV100650400; called by muse, mutect2, varscan2
- CRB2 | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs545270434, COSV63505787; called by muse, mutect2, varscan2
- CSMD3 | c.7925G>A p.G2642E (on ENST00000297405 / NM_001363185.1; = p.G2538E on NM_052900.3) | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.984); catalogued as COSV52128481; called by muse, mutect2
- CSPP1 | c.490_494del p.L164Rfs*19 (on ENST00000676605; = p.L123Rfs*19 on NM_024790.6) | Frame Shift Del (DEL) | VAF 27/282 reads (10%) | catalogued as rs763103286; called by mutect2, pindel
- DNAH5 | c.12838G>T p.D4280Y | Missense Mutation (SNP) | VAF 154/614 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs1264255228; called by muse, mutect2, varscan2
- DPF3 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 68/258 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as rs372100997; called by muse, mutect2, varscan2
- DRGX | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs1380121033; called by muse, mutect2, varscan2
- ELAPOR2 | c.1739G>A p.R580Q (on ENST00000450689 / NM_001142749.3; = p.R413Q on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.022); catalogued as rs1207509711; called by muse, mutect2
- FAM135B | c.1937C>A p.S646Y | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV52757216; called by muse, mutect2
- FCGBP | c.12391C>T p.R4131C | Missense Mutation (SNP) | VAF 29/539 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as rs542126929; called by muse, mutect2
- FCN2 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 56/982 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.057); catalogued as rs748534479, COSV52478680; called by muse, mutect2
- FKBP4 | c.639A>T p.K213N | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV50009148; called by muse, mutect2, varscan2
- FSHR | c.2003G>T p.R668M | Missense Mutation (SNP) | VAF 120/782 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100438348; called by muse, mutect2, varscan2
- GCGR | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 129/586 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs183571856; called by muse, mutect2, varscan2
- GLRB | c.557A>C p.D186A | Missense Mutation (SNP) | VAF 153/342 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1402486472; called by muse, mutect2, varscan2
- GOLGA6L2 | c.617G>A p.R206K | Missense Mutation (SNP) | VAF 130/718 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.316); catalogued as rs1381861520; called by muse, mutect2, varscan2
- GUCY1A2 | c.1424C>T p.T475I | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56491521; called by muse, mutect2, varscan2
- HAUS5 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV52549047; called by muse, mutect2, varscan2
- HTN3 | c.134C>G p.S45* | Nonsense Mutation (SNP) | VAF 10/258 reads (4%) | catalogued as COSV66879688; called by muse, mutect2
- ITPR3 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 102/316 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as rs752466498, COSV65405804; called by muse, mutect2, varscan2
- KCNH8 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 189/415 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.033); catalogued as rs761421443, COSV100108643, COSV60455533; called by muse, mutect2, varscan2
- KEAP1 | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 48/688 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1412883238, COSV50283235, COSV50291239; called by muse, mutect2
- KEAP1 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 179/464 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50260458, COSV50275012, COSV50315065; called by muse, mutect2, varscan2
- KIF6 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 181/399 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1369173598, COSV54675849; called by muse, mutect2, varscan2
- LRRIQ1 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 26/364 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV67832681; called by muse, mutect2
- MAGEB6 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100983883, COSV66872315; called by muse, mutect2, varscan2
- MAP3K15 | c.2392C>A p.R798S | Missense Mutation (SNP) | VAF 141/251 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs768703203, COSV58825457; called by muse, mutect2, varscan2
- MUC4 | c.4655C>A p.P1552H | Missense Mutation (SNP) | VAF 294/1569 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.897); catalogued as rs761789166; called by muse, varscan2
- MYH1 | c.3535C>T p.R1179C | Missense Mutation (SNP) | VAF 58/1062 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs755825265; called by muse, mutect2
- MYH8 | c.4726G>C p.D1576H | Missense Mutation (SNP) | VAF 71/331 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV67969425; called by muse, mutect2, varscan2
- MYH8 | c.1507G>T p.E503* | Nonsense Mutation (SNP) | VAF 228/1069 reads (21%) | catalogued as rs1235454816; called by muse, mutect2, varscan2
- NETO1 | c.20T>A p.V7E | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV55009406; called by muse, mutect2, varscan2
- NIBAN3 | c.681G>C p.Q227H | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.264); catalogued as COSV99962501; called by muse, mutect2
- NOTCH1 | c.1268G>T p.C423F | Missense Mutation (SNP) | VAF 84/282 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53051148; called by mutect2, varscan2
- OPRPN | c.625G>C p.A209P | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV101271071; called by muse, mutect2, varscan2
- OR6F1 | c.177G>T p.M59I | Missense Mutation (SNP) | VAF 170/542 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV100129289; called by muse, mutect2, varscan2
- ORC6 | c.703T>C p.W235R | Missense Mutation (SNP) | VAF 218/754 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770565877; called by muse, varscan2
- P2RY4 | c.349T>G p.W117G | Missense Mutation (SNP) | VAF 186/320 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.27); catalogued as COSV65736771; called by muse, mutect2, varscan2
- PABPC5 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 13/344 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.378); catalogued as COSV57039174; called by muse, mutect2
- PAMR1 | c.1451C>T p.A484V (on ENST00000619888 / NM_001001991.3; = p.A501V on NM_015430.4) | Missense Mutation (SNP) | VAF 246/601 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as rs201440508, COSV104376481; called by muse, mutect2, varscan2
- PCDHA4 | c.2213C>T p.T738M | Missense Mutation (SNP) | VAF 12/381 reads (3%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.043); catalogued as COSV63542909; called by muse, mutect2
- PCDHB13 | c.682C>G p.Q228E | Missense Mutation (SNP) | VAF 178/1623 reads (11%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.02); catalogued as COSV53393539; called by muse, mutect2, varscan2
- PCDHB3 | c.1745C>G p.P582R | Missense Mutation (SNP) | VAF 158/861 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.706); catalogued as COSV99164724; called by muse, mutect2, varscan2
- PCLO | c.12430G>T p.G4144C | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61639578; called by muse, mutect2, varscan2
- PCLO | c.3910C>T p.Q1304* | Nonsense Mutation (SNP) | VAF 22/312 reads (7%) | catalogued as COSV100434885, COSV61659338; called by muse, mutect2
- PKHD1 | c.3214A>G p.K1072E | Missense Mutation (SNP) | VAF 122/484 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.341); catalogued as rs780201606, COSV61891389; called by muse, mutect2, varscan2
- PKHD1L1 | c.9979G>A p.G3327R | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as rs370628975, COSV101005222; called by muse, varscan2
- PRRT3 | c.2860C>T p.R954W | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs751316734, COSV55976660; called by muse, mutect2, varscan2
- RC3H1 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 100/464 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1438535368, COSV51224769; called by muse, mutect2, varscan2
- REC8 | c.464T>C p.I155T | Missense Mutation (SNP) | VAF 38/400 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs771036802; called by muse, mutect2
- RYR3 | c.9391G>A p.E3131K (on ENST00000389232; = p.E3132K on NM_001036.6) | Missense Mutation (SNP) | VAF 71/316 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs747215383; called by muse, mutect2, varscan2
- SAMD14 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99557458; called by muse, mutect2, varscan2
- SEC24A | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765647790, COSV59750172; called by muse, mutect2, varscan2
- SF3B4 | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.129); catalogued as COSV54964958, COSV99641142; called by muse, mutect2, varscan2
- SLC8A2 | c.1973G>A p.R658Q | Missense Mutation (SNP) | VAF 222/452 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.372); catalogued as rs750186208, COSV52640531; called by muse, mutect2, varscan2
- SPDEF | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs2233640; called by muse, mutect2
- SPINK6 | c.184T>A p.C62S | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57777900; called by muse, mutect2, varscan2
- SPN | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.041); catalogued as rs144554729; called by muse, mutect2, varscan2
- ST18 | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV52494262; called by muse, mutect2
- SVIL | c.5317G>A p.G1773R (on ENST00000355867 / NM_021738.3; = p.G1347R on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/396 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778601433; called by muse, mutect2
- SYNE3 | c.1058G>A p.R353K | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.11); catalogued as rs748070235; called by muse, mutect2, varscan2
- SYT6 | c.962G>C p.R321P (on ENST00000610222 / NM_001366225.1; = p.R236P on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 190/489 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65773471, COSV65774250; called by muse, mutect2, varscan2
- TBC1D9 | c.693C>G p.F231L | Missense Mutation (SNP) | VAF 17/371 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV104437119; called by muse, mutect2
- TLN1 | c.6178G>T p.D2060Y | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV59212732; called by muse, mutect2, varscan2
- TMEFF2 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 108/477 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV55842385; called by muse, mutect2, varscan2
- TOP3A | c.487G>T p.V163L | Missense Mutation (SNP) | VAF 301/974 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs374761934, COSV58178159; called by muse, mutect2, varscan2
- TRIM46 | c.1994C>A p.S665* | Nonsense Mutation (SNP) | VAF 143/553 reads (26%) | catalogued as COSV58111031; called by muse, mutect2, varscan2
- TRIO | c.5036G>T p.R1679L | Missense Mutation (SNP) | VAF 159/616 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as COSV100711154, COSV60085416; called by muse, mutect2, varscan2
- TRPA1 | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 64/878 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.381); catalogued as COSV51562672; called by muse, mutect2
- TTN | c.53752C>G p.L17918V (on ENST00000591111; = p.L10494V on NM_003319.4) | Missense Mutation (SNP) | VAF 112/436 reads (26%) | PolyPhen benign (0.11); catalogued as COSV59975426; called by muse, mutect2, varscan2
- UNC5A | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 59/341 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs780569422, COSV99994516; called by muse, mutect2, varscan2
- URB2 | c.1309G>T p.D437Y | Missense Mutation (SNP) | VAF 109/352 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV50982396; called by muse, mutect2, varscan2
- VAV1 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV58384289; called by muse, mutect2, varscan2
- XDH | c.1041C>T p.S347= | Splice Region (SNP) | VAF 119/872 reads (14%) | catalogued as rs375950132; ClinVar: likely benign; called by mutect2, varscan2
- ZFHX4 | c.2303G>T p.R768L | Missense Mutation (SNP) | VAF 47/532 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV104378927; called by muse, mutect2
- ZNF729 | c.2284C>A p.H762N | Missense Mutation (SNP) | VAF 90/280 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV62602758; called by muse, mutect2, varscan2
- ZNF800 | c.1624C>T p.H542Y | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56180396; called by muse, mutect2
- ZNF804A | c.3262C>A p.Q1088K | Missense Mutation (SNP) | VAF 79/261 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.115); catalogued as COSV56434009; called by muse, mutect2, varscan2
- ZNF804B | c.3866C>A p.T1289K | Missense Mutation (SNP) | VAF 64/286 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV60816455; called by muse, mutect2, varscan2
- ZNF90 | c.1142C>G p.S381C | Missense Mutation (SNP) | VAF 49/472 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.326); catalogued as COSV101367151; called by muse, mutect2, varscan2
- ABCA13 | c.4885G>T p.G1629C | Missense Mutation (SNP) | VAF 160/420 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ABCC3 | c.2794G>T p.V932L | Missense Mutation (SNP) | VAF 104/365 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ABCC8 | c.2041-4G>A | Splice Region (SNP) | VAF 38/452 reads (8%) | called by muse, mutect2
- AC136428.1 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 157/836 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ACTN2 | c.1824del p.T609Pfs*6 | Frame Shift Del (DEL) | VAF 195/891 reads (22%) | called by mutect2, pindel, varscan2
- ADAMTS16 | c.1394G>C p.R465P | Missense Mutation (SNP) | VAF 103/432 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- ADCY8 | c.3713C>A p.P1238H | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.094); called by muse, mutect2
- ADGRD1 | c.102A>T p.P34= | Splice Region (SNP) | VAF 109/531 reads (21%) | called by muse, mutect2, varscan2
- ALAD | c.778A>T p.I260F | Missense Mutation (SNP) | VAF 159/760 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- ANK3 | c.3174-2A>T p.X1058_splice (on ENST00000280772 / NM_001320874.2; = p.X192_splice on NM_001149.3) | Splice Site (SNP) | VAF 33/225 reads (15%) | called by muse, mutect2, varscan2
- ANKRD44 | c.718A>T p.N240Y | Missense Mutation (SNP) | VAF 119/552 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARFGEF3 | c.2160T>A p.N720K | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ASPM | c.5338G>A p.V1780I | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- ATG2B | c.4001G>T p.R1334L | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.85); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- ATP10A | c.4030G>T p.V1344F | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ATP10A | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 22/387 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); called by muse, mutect2
- ATP1A2 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 151/594 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BRD3 | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 142/508 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- C12orf42 | c.978G>T p.R326S | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- CACNB2 | c.120+8G>T | Splice Region (SNP) | VAF 21/197 reads (11%) | called by muse, mutect2, varscan2
- CBWD6 | c.1081+7C>A | Splice Region (SNP) | VAF 98/452 reads (22%) | called by muse, varscan2
- CENPE | c.6001C>T p.Q2001* | Nonsense Mutation (SNP) | VAF 116/298 reads (39%) | called by muse, mutect2, varscan2
- CFAP74 | c.1142C>A p.P381H | Missense Mutation (SNP) | VAF 42/496 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.046); called by muse, mutect2
- CNOT1 | c.2762_2764del p.I921_E922delinsK | In Frame Del (DEL) | VAF 268/1011 reads (27%) | called by mutect2, pindel*, varscan2*
- COG5 | c.1027-1G>T p.X343_splice | Splice Site (SNP) | VAF 178/447 reads (40%) | called by muse, mutect2, varscan2
- CPA6 | c.749A>T p.D250V | Missense Mutation (SNP) | VAF 123/324 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CPNE8 | c.1259A>G p.N420S | Missense Mutation (SNP) | VAF 15/279 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.262); called by muse, mutect2
- CREG1 | c.19G>C p.G7R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYB5R3 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 540/889 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCBLD1 | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 30/333 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.129); called by muse, mutect2
- DCHS1 | c.1366G>T p.A456S | Missense Mutation (SNP) | VAF 40/544 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.86); called by muse, mutect2
- DDHD2 | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 121/373 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DDX24 | c.1151C>G p.P384R | Missense Mutation (SNP) | VAF 118/495 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- DDX28 | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 147/531 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DGKQ | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- DLG2 | c.1014C>A p.D338E | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DMWD | c.1586A>T p.Q529L | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- DNAH6 | c.1856A>T p.E619V | Missense Mutation (SNP) | VAF 44/271 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- DST | c.8681A>T p.Q2894L | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.121); called by muse, mutect2
- EIF1AY | c.350A>T p.E117V | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- EML5 | c.2884C>G p.R962G | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENPP1 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by mutect2, varscan2
- ESRRG | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 132/357 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM76A | c.808del p.T270Pfs*17 | Frame Shift Del (DEL) | VAF 159/415 reads (38%) | called by mutect2, pindel, varscan2
- FAM83A | c.34A>T p.K12* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- FAM98B | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 181/547 reads (33%) | called by muse, mutect2, varscan2
- FAP | c.1120T>A p.Y374N | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FASTKD1 | c.1870G>C p.E624Q | Missense Mutation (SNP) | VAF 18/424 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.024); called by muse, mutect2
- FNDC1 | c.4573A>G p.N1525D | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.419); called by muse, mutect2
- FOXI3 | c.877G>A p.G293S | Missense Mutation (SNP) | VAF 304/828 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FREM2 | c.9498C>A p.S3166R | Missense Mutation (SNP) | VAF 196/513 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- FSIP2 | c.8520G>C p.L2840F | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GGT2 | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 110/352 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- GIGYF2 | c.2579G>A p.R860Q | Missense Mutation (SNP) | VAF 239/586 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, varscan2
- GLT1D1 | c.291C>A p.N97K | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- GOLGA8M | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 320/1190 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPCPD1 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 80/307 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.136); called by muse, varscan2
- GSDMA | c.1138G>T p.G380C | Missense Mutation (SNP) | VAF 152/608 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GSDMD | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 21/283 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); called by muse, mutect2
- GUCY2D | c.2969del p.G990Afs*31 | Frame Shift Del (DEL) | VAF 151/681 reads (22%) | called by mutect2, pindel, varscan2
- H2AC8 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 48/544 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); called by muse, mutect2
- HDAC4 | c.517A>G p.M173V | Missense Mutation (SNP) | VAF 221/619 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- HDAC5 | c.2938G>A p.A980T | Missense Mutation (SNP) | VAF 99/410 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- HIVEP2 | c.6260A>T p.H2087L | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HSD17B11 | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 106/254 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ICA1 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 221/606 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IDI1 | c.132G>C p.R44S | Missense Mutation (SNP) | VAF 117/354 reads (33%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHV5-51 | c.11C>A p.T4N | Missense Mutation (SNP) | VAF 54/290 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- IL1B | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 84/931 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- INSYN2A | c.1036T>A p.C346S | Missense Mutation (SNP) | VAF 30/410 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2
- KIAA0319 | c.2728A>T p.T910S | Missense Mutation (SNP) | VAF 91/205 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KIAA0319 | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 182/483 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF26A | c.4183G>C p.V1395L | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLK8 | c.109C>A p.H37N | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- KMT2D | c.11728C>T p.Q3910* | Nonsense Mutation (SNP) | VAF 128/372 reads (34%) | called by muse, mutect2, varscan2
- KRTAP3-3 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 60/938 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.112); called by muse, mutect2
- KRTAP9-8 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 371/1116 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LAMA5 | c.4898C>A p.A1633D | Missense Mutation (SNP) | VAF 17/387 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- LTBP1 | c.141del p.P49Rfs*173 | Frame Shift Del (DEL) | VAF 14/156 reads (9%) | called by mutect2, pindel
- MAD1L1 | c.515G>T p.S172I | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- MAP3K4 | c.1577A>G p.Y526C | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAST1 | c.3650C>A p.S1217* | Nonsense Mutation (SNP) | VAF 14/234 reads (6%) | called by muse, mutect2
- MASTL | c.1390A>T p.T464S | Missense Mutation (SNP) | VAF 149/304 reads (49%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBD5 | c.860C>A p.S287* | Nonsense Mutation (SNP) | VAF 183/806 reads (23%) | called by muse, mutect2, varscan2
- MED12L | c.1358-1G>A p.X453_splice | Splice Site (SNP) | VAF 68/331 reads (21%) | called by muse, mutect2, varscan2
- MKRN3 | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 124/523 reads (24%) | called by muse, mutect2, varscan2
- MMP25 | c.1371G>A p.W457* | Nonsense Mutation (SNP) | VAF 19/150 reads (13%) | called by muse, mutect2, varscan2
- MSANTD4 | c.251G>C p.R84T | Missense Mutation (SNP) | VAF 81/212 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MTMR11 | c.940G>A p.D314N (on ENST00000439741 / NM_001145862.2; = p.D242N on NM_181873.3) | Missense Mutation (SNP) | VAF 21/297 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- MTMR8 | c.170C>A p.T57N | Missense Mutation (SNP) | VAF 56/93 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MUC16 | c.36017C>A p.T12006N | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- NAA35 | c.1673G>T p.R558L | Missense Mutation (SNP) | VAF 88/407 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- NAMPT | c.1286G>T p.R429L | Missense Mutation (SNP) | VAF 39/366 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NAV2 | c.1762C>G p.P588A (on ENST00000396087 / NM_001244963.2; = p.P565A on NM_145117.5) | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NEBL | c.749A>T p.E250V | Missense Mutation (SNP) | VAF 104/262 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- NECTIN3 | c.692A>T p.Y231F | Missense Mutation (SNP) | VAF 101/532 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEK9 | c.2270G>A p.G757D | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated, low confidence (0.54); PolyPhen possibly damaging (0.482); called by muse, mutect2
- NIPAL2 | c.386T>G p.I129S | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2
- NLGN1 | c.1891T>A p.S631T | Missense Mutation (SNP) | VAF 62/782 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- NRCAM | c.2360G>T p.R787L (on ENST00000379028 / NM_001371124.1; = p.R771L on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 232/610 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OPRPN | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR14C36 | c.102G>T p.L34F | Missense Mutation (SNP) | VAF 91/363 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- OR2T12 | c.691G>T p.A231S | Missense Mutation (SNP) | VAF 218/798 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- OR4N2 | c.218A>T p.Y73F | Missense Mutation (SNP) | VAF 48/339 reads (14%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- OR5A2 | c.875G>A p.S292N | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- PARP2 | c.1553del p.L518Rfs*14 | Frame Shift Del (DEL) | VAF 14/87 reads (16%) | called by pindel, varscan2
- PCDH15 | c.4829A>T p.D1610V | Missense Mutation (SNP) | VAF 134/447 reads (30%) | SIFT tolerated, low confidence (0.2); called by muse, mutect2, varscan2
- PCDH15 | c.1955T>A p.I652N | Missense Mutation (SNP) | VAF 156/494 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHGA8 | c.1693C>A p.P565T | Missense Mutation (SNP) | VAF 103/508 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PHEX | c.1409G>C p.R470T | Missense Mutation (SNP) | VAF 28/395 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.085); called by muse, mutect2
- PLCL1 | c.505G>T p.G169W | Missense Mutation (SNP) | VAF 86/319 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLQ | c.1763G>T p.W588L | Missense Mutation (SNP) | VAF 208/688 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- POLR1B | c.2950A>C p.S984R | Missense Mutation (SNP) | VAF 178/559 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PORCN | c.1142G>A p.C381Y (on ENST00000326194 / NM_203475.3; = p.C370Y on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 335/592 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPARGC1A | c.2143G>A p.D715N | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PPOX | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 295/899 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PRMT3 | c.298-1G>T p.X100_splice | Splice Site (SNP) | VAF 17/167 reads (10%) | called by muse, mutect2, varscan2
- PTPN18 | c.1313T>C p.L438P | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PTPRQ | c.5957A>T p.D1986V (on ENST00000616559; = p.D1944V on NM_001145026.2) | Missense Mutation (SNP) | VAF 95/307 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- PXDNL | c.4142A>G p.E1381G | Missense Mutation (SNP) | VAF 68/262 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PXDNL | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 70/238 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RGPD3 | c.2110G>C p.E704Q | Missense Mutation (SNP) | VAF 44/794 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.746); called by muse, mutect2
- RGS18 | c.601T>G p.L201V | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.081); called by muse, mutect2
- RICTOR | c.334C>G p.Q112E | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RIPOR1 | c.1594G>A p.D532N (on ENST00000379312 / NM_001193522.2; = p.D528N on NM_024519.4) | Missense Mutation (SNP) | VAF 29/450 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- ROS1 | c.4451C>A p.T1484N | Missense Mutation (SNP) | VAF 123/489 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RP1 | c.2565G>T p.Q855H | Missense Mutation (SNP) | VAF 48/289 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SEC31A | c.2412C>A p.Y804* (on ENST00000355196 / NM_001318120.1; = p.Y765* on NM_016211.4) | Nonsense Mutation (SNP) | VAF 36/385 reads (9%) | called by muse, mutect2
- SERINC1 | c.483T>G p.F161L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SGTA | c.331G>T p.V111L | Missense Mutation (SNP) | VAF 150/466 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SIRT7 | c.408-4G>T | Splice Region (SNP) | VAF 117/359 reads (33%) | called by muse, mutect2, varscan2
- SLC15A5 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- SLC17A6 | c.1169G>T p.C390F | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- SNX29 | c.1420A>T p.T474S | Missense Mutation (SNP) | VAF 62/397 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SOX11 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPATA17 | c.519G>T p.Q173H | Missense Mutation (SNP) | VAF 111/340 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPATA31D1 | c.3571G>T p.V1191F | Missense Mutation (SNP) | VAF 71/402 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- SPTA1 | c.3538G>C p.G1180R | Missense Mutation (SNP) | VAF 105/539 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- TDRD6 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2
- TECTA | c.1163A>C p.Y388S | Missense Mutation (SNP) | VAF 140/386 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TFEB | c.1415A>G p.E472G | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, varscan2
- THBD | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.07); called by muse, mutect2
- TMED8 | c.593A>C p.H198P | Missense Mutation (SNP) | VAF 210/850 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TOPAZ1 | c.4231T>A p.C1411S | Missense Mutation (SNP) | VAF 138/377 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPC6 | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 56/564 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.01); called by muse, mutect2
- TRPM7 | c.3475del p.K1159Nfs*4 | Frame Shift Del (DEL) | VAF 74/399 reads (19%) | called by mutect2, pindel, varscan2
- TTN | c.28320G>T p.E9440D (on ENST00000591111; = p.E8513D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/428 reads (24%) | PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- UFL1 | c.277A>T p.I93F | Missense Mutation (SNP) | VAF 59/212 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- UFM1 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 74/834 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.933); called by muse, mutect2
- VWF | c.7525dup p.D2509Gfs*24 | Frame Shift Ins (INS) | VAF 146/621 reads (24%) | called by mutect2, pindel, varscan2
- WDFY4 | c.1490A>T p.D497V | Missense Mutation (SNP) | VAF 47/478 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2
- ZNF37A | c.1280C>A p.T427N | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF398 | c.910A>T p.T304S (on ENST00000475153 / NM_170686.3; = p.T133S on NM_020781.4) | Missense Mutation (SNP) | VAF 135/614 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF470 | c.1131C>A p.F377L | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF536 | c.3837T>A p.F1279L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ZNF622 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, varscan2
- ZNF726 | c.3+1G>A p.X1_splice | Splice Site (SNP) | VAF 34/198 reads (17%) | called by muse, mutect2, varscan2
- ZNF729 | c.1871G>T p.G624V | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZYG11B | c.1764T>G p.S588R | Missense Mutation (SNP) | VAF 244/524 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ABHD15 | c.447G>T p.R149= | Silent (SNP) | VAF 38/189 reads (20%) | called by muse, mutect2, varscan2
- ABT1 | c.171C>T p.F57= | Silent (SNP) | VAF 130/379 reads (34%) | called by muse, mutect2, varscan2
- ADAMTS10 | c.939C>T p.S313= | Silent (SNP) | VAF 66/664 reads (10%) | catalogued as rs1218619703, COSV54354871; called by muse, mutect2
- AK5 | c.1032T>A p.I344= (on ENST00000354567 / NM_174858.3; = p.I318= on NM_012093.4) | Silent (SNP) | VAF 101/245 reads (41%) | catalogued as rs1277043417; called by muse, mutect2, varscan2
- ALCAM | c.1707A>G p.E569= | Silent (SNP) | VAF 14/315 reads (4%) | called by muse, mutect2
- BRD4 | c.1530G>A p.R510= | Silent (SNP) | VAF 46/129 reads (36%) | called by muse, mutect2, varscan2
- CDK5R1 | c.414G>T p.T138= | Silent (SNP) | VAF 48/157 reads (31%) | catalogued as rs1231900834; called by muse, mutect2, varscan2
- CMYA5 | c.9462G>A p.G3154= | Silent (SNP) | VAF 69/168 reads (41%) | catalogued as rs1182566614; called by muse, mutect2, varscan2
- COL24A1 | c.3219T>G p.P1073= | Silent (SNP) | VAF 24/331 reads (7%) | called by muse, mutect2
- COL4A2 | c.4986C>A p.R1662= | Silent (SNP) | VAF 143/374 reads (38%) | called by muse, mutect2, varscan2
- CSMD1 | c.5628C>T p.T1876= (on ENST00000520002; = p.T1875= on NM_033225.6) | Silent (SNP) | VAF 76/281 reads (27%) | called by muse, mutect2, varscan2
- CYP26B1 | c.1530C>T p.A510= | Silent (SNP) | VAF 40/290 reads (14%) | catalogued as rs1162035676; called by muse, mutect2, varscan2
- CYP4F8 | c.486C>T p.P162= | Silent (SNP) | VAF 55/344 reads (16%) | catalogued as rs751028928; called by muse, mutect2, varscan2
- DDHD2 | c.15G>A p.Q5= | Silent (SNP) | VAF 80/378 reads (21%) | catalogued as rs1463268146; called by muse, varscan2
- DENND10 | c.303G>A p.K101= | Silent (SNP) | VAF 42/490 reads (9%) | catalogued as rs745767471; called by muse, mutect2
- DEPDC1B | c.21G>T p.G7= | Silent (SNP) | VAF 100/239 reads (42%) | called by muse, mutect2, varscan2
- DNAH10 | c.4350A>C p.A1450= (on ENST00000409039; = p.A1389= on NM_207437.3) | Silent (SNP) | VAF 22/327 reads (7%) | called by muse, mutect2
- DNAH10 | c.5283G>T p.A1761= (on ENST00000409039; = p.A1700= on NM_207437.3) | Silent (SNP) | VAF 186/872 reads (21%) | catalogued as COSV68988559; called by muse, mutect2, varscan2
- DNAH5 | c.6388T>C p.L2130= | Silent (SNP) | VAF 9/172 reads (5%) | called by muse, mutect2
- DNAI3 | c.54A>G p.P18= | Silent (SNP) | VAF 200/430 reads (47%) | called by muse, mutect2, varscan2
- DOCK2 | c.1107C>T p.A369= | Silent (SNP) | VAF 26/133 reads (20%) | catalogued as rs762640096; called by muse, mutect2, varscan2
- DST | c.11679G>T p.L3893= (on ENST00000361203 / NM_001374722.1; = p.L1481= on NM_015548.5) | Silent (SNP) | VAF 53/193 reads (27%) | catalogued as rs1257205198, COSV99749326; called by muse, mutect2, varscan2
- EPB41L3 | c.1563C>A p.A521= | Silent (SNP) | VAF 70/260 reads (27%) | called by muse, mutect2, varscan2
- EPHA3 | c.672G>A p.V224= | Silent (SNP) | VAF 32/168 reads (19%) | catalogued as COSV60718353; called by muse, mutect2, varscan2
- FNDC1 | c.546G>T p.L182= | Silent (SNP) | VAF 189/735 reads (26%) | called by muse, mutect2, varscan2
- GFRA2 | c.1209G>T p.T403= | Silent (SNP) | VAF 40/188 reads (21%) | catalogued as rs528194056; called by muse, mutect2, varscan2
- H2AC8 | c.27C>T p.G9= | Silent (SNP) | VAF 48/550 reads (9%) | called by muse, mutect2
- IGSF11 | c.936C>T p.T312= (on ENST00000393775 / NM_001015887.3; = p.T311= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 199/652 reads (31%) | called by muse, mutect2, varscan2
- INAVA | c.1290G>A p.T430= | Silent (SNP) | VAF 26/334 reads (8%) | catalogued as COSV66256011, COSV66257012; called by muse, mutect2
- INO80 | c.1596A>G p.L532= | Silent (SNP) | VAF 103/340 reads (30%) | catalogued as rs773643363; called by muse, mutect2, varscan2
- INO80D | c.669G>C p.A223= | Silent (SNP) | VAF 174/452 reads (38%) | catalogued as COSV68958305; called by muse, mutect2, varscan2
- KCNN3 | c.1002C>T p.I334= | Silent (SNP) | VAF 58/716 reads (8%) | called by muse, mutect2
- KCNT1 | c.1722G>A p.V574= (on ENST00000488444; = p.V593= on NM_020822.3) | Silent (SNP) | VAF 65/163 reads (40%) | catalogued as rs748744989; called by muse, mutect2, varscan2
- KL | c.2304A>G p.G768= | Silent (SNP) | VAF 298/659 reads (45%) | called by muse, mutect2, varscan2
- KLHDC8A | c.564G>A p.A188= | Silent (SNP) | VAF 36/462 reads (8%) | catalogued as rs150366273; called by muse, mutect2
- KSR2 | c.963C>A p.R321= | Silent (SNP) | VAF 134/524 reads (26%) | catalogued as COSV60366545; called by muse, mutect2, varscan2
- L3MBTL4 | c.1149G>T p.G383= | Silent (SNP) | VAF 86/331 reads (26%) | called by muse, mutect2, varscan2
- LMAN1 | c.891A>G p.Q297= | Silent (SNP) | VAF 83/642 reads (13%) | catalogued as rs750403698, COSV99195388; called by muse, mutect2, varscan2
- MUC3A | c.132C>T p.L44= | Silent (SNP) | VAF 154/349 reads (44%) | called by muse, mutect2, varscan2
- MXRA8 | c.963G>A p.A321= | Silent (SNP) | VAF 129/248 reads (52%) | catalogued as COSV58510306; called by muse, mutect2, varscan2
- NELL1 | c.2163A>T p.G721= | Silent (SNP) | VAF 43/100 reads (43%) | called by muse, varscan2
- NUTM2B | c.1635C>A p.G545= | Silent (SNP) | VAF 36/871 reads (4%) | called by muse, mutect2
- OR11G2 | c.759G>C p.V253= | Silent (SNP) | VAF 146/931 reads (16%) | called by muse, varscan2
- OR2A2 | c.426C>A p.I142= | Silent (SNP) | VAF 88/347 reads (25%) | called by muse, mutect2, varscan2
- OR2L8 | c.195C>T p.L65= | Silent (SNP) | VAF 104/476 reads (22%) | called by muse, mutect2, varscan2
- OR2T12 | c.45C>G p.L15= | Silent (SNP) | VAF 48/181 reads (27%) | called by muse, mutect2, varscan2
- PALM | c.12G>T p.L4= | Silent (SNP) | VAF 24/138 reads (17%) | called by muse, mutect2, varscan2
- PCDH11X | c.3240C>T p.S1080= | Silent (SNP) | VAF 266/511 reads (52%) | called by muse, mutect2, varscan2
- PCDHGA11 | c.630G>A p.L210= | Silent (SNP) | VAF 94/479 reads (20%) | called by muse, mutect2, varscan2
- PRKAA2 | c.354G>A p.R118= | Silent (SNP) | VAF 276/536 reads (51%) | called by muse, mutect2, varscan2
- RBBP6 | c.5055G>T p.V1685= | Silent (SNP) | VAF 77/398 reads (19%) | called by muse, mutect2, varscan2
- ROBO2 | c.2083C>A p.R695= | Silent (SNP) | VAF 93/325 reads (29%) | catalogued as rs1005812838, COSV59919519; called by muse, mutect2, varscan2
- SELENOI | c.45T>C p.F15= | Silent (SNP) | VAF 143/273 reads (52%) | catalogued as rs1167374846; called by muse, mutect2, varscan2
- SERPINA5 | c.183C>A p.P61= | Silent (SNP) | VAF 62/259 reads (24%) | catalogued as COSV61573797, COSV61573962; called by muse, mutect2, varscan2
- SHANK1 | c.1584C>A p.A528= | Silent (SNP) | VAF 53/109 reads (49%) | catalogued as COSV53246601, COSV53253729; called by muse, mutect2, varscan2
- SLAMF1 | c.462G>A p.E154= | Silent (SNP) | VAF 91/361 reads (25%) | called by muse, mutect2, varscan2
- SLC26A3 | c.1629T>A p.P543= | Silent (SNP) | VAF 421/997 reads (42%) | called by muse, mutect2, varscan2
- SLFN14 | c.1401G>A p.V467= | Silent (SNP) | VAF 85/281 reads (30%) | called by muse, mutect2, varscan2
- SNX14 | c.600G>A p.K200= (on ENST00000314673 / NM_001350535.1; = p.K156= on NM_020468.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 39/1140 reads (3%) | catalogued as rs1197884696; called by muse, mutect2
- SOWAHD | c.154C>A p.R52= | Silent (SNP) | VAF 44/82 reads (54%) | called by muse, mutect2, varscan2
- STOML3 | c.321C>A p.T107= | Silent (SNP) | VAF 73/158 reads (46%) | called by muse, mutect2, varscan2
- SYNC | c.972C>T p.L324= | Silent (SNP) | VAF 38/408 reads (9%) | called by muse, mutect2
- TSC2 | c.1305C>T p.H435= | Silent (SNP) | VAF 143/404 reads (35%) | catalogued as rs766461065; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTLL2 | c.1281C>A p.A427= | Silent (SNP) | VAF 141/412 reads (34%) | called by muse, mutect2, varscan2
- WDFY4 | c.7344G>T p.L2448= | Silent (SNP) | VAF 70/235 reads (30%) | called by muse, mutect2, varscan2
- WDR49 | c.1803T>C p.Y601= (on ENST00000308378 / NM_001366158.1; = p.Y942= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/305 reads (11%) | catalogued as rs774779867; called by muse, mutect2, varscan2
- XKR3 | c.903G>T p.V301= | Silent (SNP) | VAF 234/407 reads (57%) | called by muse, mutect2, varscan2
- ZIM3 | c.1050C>T p.V350= | Silent (SNP) | VAF 10/246 reads (4%) | called by muse, mutect2
- ZNF417 | c.1200A>T p.R400= | Silent (SNP) | VAF 109/221 reads (49%) | called by muse, mutect2, varscan2
- ZNF587 | c.1284A>G p.R428= | Silent (SNP) | VAF 20/282 reads (7%) | called by muse, mutect2
- ZNF71 | c.1050C>A p.G350= | Silent (SNP) | VAF 94/201 reads (47%) | called by muse, mutect2, varscan2
- ZNF875 | c.1320T>C p.P440= | Silent (SNP) | VAF 143/447 reads (32%) | called by muse, mutect2, varscan2
- ABR | c.62-89C>T | Intron (SNP) | VAF 12/160 reads (8%) | catalogued as rs560330854; called by muse, mutect2
- AC093525.2 | c.*477A>T | 3'UTR (SNP) | VAF 26/420 reads (6%) | called by muse, mutect2
- AC133561.1 | n.1350G>A | RNA (SNP) | VAF 66/230 reads (29%) | catalogued as rs766400836; called by mutect2, varscan2
- AC235097.1 | n.330A>G | RNA (SNP) | VAF 49/106 reads (46%) | called by muse, mutect2, varscan2
- AGFG2 | c.-26G>A | 5'UTR (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- AGTPBP1 | c.-44A>G | 5'UTR (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- AMPH | c.1182+381C>A | Intron (SNP) | VAF 166/496 reads (33%) | called by muse, mutect2, varscan2
- APBA2 | c.*43C>A | 3'UTR (SNP) | VAF 52/219 reads (24%) | called by muse, mutect2, varscan2
- C5orf17 | n.390A>G | RNA (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- COPS6 | c.-14C>A | 5'UTR (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2
- CYP3A7-CYP3A51P | chr7:99685219 C>T | 3'Flank (SNP) | VAF 64/830 reads (8%) | catalogued as rs749881246; called by muse, mutect2
- DENND2B | c.-25-25482T>G | Intron (SNP) | VAF 112/289 reads (39%) | called by muse, mutect2, varscan2
- DLC1 | c.1348+44G>C | Intron (SNP) | VAF 18/250 reads (7%) | called by muse, mutect2
- DPP6 | c.627+21003C>A | Intron (SNP) | VAF 112/413 reads (27%) | called by muse, mutect2, varscan2
- EIF3I | chr1:32222349 G>T | 5'Flank (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- EYS | c.1767-6487C>T | Intron (SNP) | VAF 96/586 reads (16%) | called by muse, mutect2, varscan2
- FAAP20 | chr1:2186164 A>T | 3'Flank (SNP) | VAF 30/59 reads (51%) | called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446233 C>T | 3'Flank (SNP) | VAF 179/732 reads (24%) | called by muse, mutect2, varscan2
- HELLPAR | n.204946C>T | RNA (SNP) | VAF 140/508 reads (28%) | called by muse, mutect2, varscan2
- IQSEC1 | c.2847+1635G>C | Intron (SNP) | VAF 92/190 reads (48%) | called by muse, mutect2, varscan2
- LINC01551 | n.1254+18585C>G | Intron (SNP) | VAF 66/286 reads (23%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1094841 C>T | 3'Flank (SNP) | VAF 171/606 reads (28%) | catalogued as rs1242455776; called by muse, varscan2
- NDRG4 | c.-87C>T | 5'UTR (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- NDUFA13 | chr19:19516064 C>A | 5'Flank (SNP) | VAF 118/355 reads (33%) | called by muse, mutect2, varscan2
- NELL2 | c.-16T>G | 5'UTR (SNP) | VAF 504/1090 reads (46%) | called by muse, mutect2, varscan2
- OBSCN | c.11659+4836C>T | Intron (SNP) | VAF 38/666 reads (6%) | catalogued as rs1269501370; called by muse, mutect2
- OR5P1P | n.346G>A | RNA (SNP) | VAF 20/260 reads (8%) | catalogued as rs1300982683; called by muse, mutect2
- PEX1 | c.-40G>T | 5'UTR (SNP) | VAF 26/75 reads (35%) | called by muse, mutect2, varscan2
- PLEKHG6 | c.139-510A>G | Intron (SNP) | VAF 25/97 reads (26%) | called by muse, mutect2, varscan2
- PNKD | c.237-16456C>A | Intron (SNP) | VAF 30/213 reads (14%) | called by muse, mutect2, varscan2
- RFK | chr9:76399074 G>T | 5'Flank (SNP) | VAF 382/1333 reads (29%) | called by muse, mutect2, varscan2
- RNFT2 | c.*3242T>A | 3'UTR (SNP) | VAF 112/483 reads (23%) | called by muse, mutect2, varscan2
- SETD2 | c.-48G>T | 5'UTR (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- SFTPA2 | c.-23-11C>T | Intron (SNP) | VAF 31/113 reads (27%) | called by muse, mutect2, varscan2
- SLC5A5 | c.-86C>G | 5'UTR (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-2481T>A | Intron (SNP) | VAF 76/366 reads (21%) | called by muse, mutect2, varscan2
- SPTLC3 | c.303+116A>G | Intron (SNP) | VAF 9/132 reads (7%) | called by muse, mutect2
- TNFRSF10B | c.*588G>T | 3'UTR (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- TNN | c.-49C>A | 5'UTR (SNP) | VAF 129/497 reads (26%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.1776+607C>T | Intron (SNP) | VAF 60/437 reads (14%) | catalogued as rs962829609; called by muse, varscan2
- TRAPPC12 | c.1776+635G>T | Intron (SNP) | VAF 75/509 reads (15%) | called by muse, varscan2
- TSN | c.67-660C>T | Intron (SNP) | VAF 14/238 reads (6%) | catalogued as rs1202689476, COSV67606000; called by muse, mutect2
- TTYH1 | c.*33C>A | 3'UTR (SNP) | VAF 115/208 reads (55%) | catalogued as rs568496543; called by muse, mutect2, varscan2
- UVSSA | c.*9340G>T | 3'UTR (SNP) | VAF 180/806 reads (22%) | called by muse, varscan2
- VPS29 | c.3+387A>G | Intron (SNP) | VAF 180/762 reads (24%) | catalogued as rs997870121; called by muse, varscan2
- ZNF461 | c.*806T>A | 3'UTR (SNP) | VAF 18/426 reads (4%) | called by muse, mutect2
